Gene-level copy-number profile of tumor specimen TCGA-A6-5665-01B from TCGA case TCGA-A6-5665, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 84.6 years (30,915 days).
Specimen TCGA-A6-5665-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.24eaa47c-2d95-433c-90e0-17686236a9b1.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-5665-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 349 have no estimate.
https://portal.gdc.cancer.gov/files/b24d6018-0f90-4a81-8fb9-0f0e760faaf4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 523; copy number 1: 1,477; copy number 2: 58,119; copy number 5: 144; copy number 10: 1; copy number 13: 4; copy number 20: 5; copy number 22: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-5665-01A-01D-1649-01): tumor purity 0.72, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:78,352,597–78,367,623, 2 genes (within-gene range 0–32): AC010163.2, SNORA71.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 155 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:121,099,108–121,099,774, 1 gene, copy number 10: AC078857.1.
- chr6:32,459,821–32,589,848, 5 genes, copy number 20 (within-gene range 2–20): HLA-DRB9, HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1.
- chr14:105,419,820–106,481,706, 143 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr14:106,489,345–106,489,756, 1 gene, copy number 5: IGHVIV-44-1.
- chr15:25,054,210–25,062,427, 4 genes, copy number 13: SNORD116-2, SNORD116-3, SNORD116-4, SNORD116-5.
- chr22:25,349,543–25,350,322, 1 gene, copy number 22: AL022324.2.

Autosomal genes at a single copy (total copy number 1): 866. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
